Gene-level copy-number profile of tumor specimen TCGA-ER-A2ND-06A from TCGA case TCGA-ER-A2ND, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 58.9 years (21,520 days).
Specimen TCGA-ER-A2ND-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.5e393aa6-a124-4dd9-a295-d33881adfe22.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-ER-A2ND-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 818 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/0149f653-a2aa-4cdc-adff-c1ca5909a6e8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 73; copy number 1: 870; copy number 2: 20,554; copy number 3: 19,581; copy number 4: 17,595; copy number 5: 1,044; copy number 6: 43; copy number 7: 35; copy number 10: 10.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-ER-A2ND-06A-11D-A194-01): tumor purity 0.72, ploidy 2.88, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 69 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:201,116,154–201,780,956, 31 genes (within-gene range 0–2): CFLAR, IMPDH1P10, CFLAR-AS1, RNU7-45P, RPL38P5, AC007283.1, CASP10, MTND5P25, MTND4P23, MTND4LP13, CASP8, FLACC1, TRAK2, STRADB, SCYL2P1, Y_RNA, C2CD6, MTCO2P16, MTATP6P16, MTCO3P16, MTND3P16, MTND4LP16, MTND4P29, MTND5P31, TMEM237, ENO1P4, AC007279.1, MPP4, RNU6-651P, ALS2, RPS2P16.
- chr9:21,802,636–22,455,740, 16 genes (within-gene range 0–2): MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1, DMRTA1.
- chr12:110,491,083–110,845,963, 12 genes (within-gene range 0–2): VPS29, AC002350.1, AC002350.2, RAD9B, PPTC7, TCTN1, RN7SL387P, HVCN1, PPP1CC, AC144522.1, AC002375.1, RPL29P25.
- chr17:68,206,076–68,601,367, 10 genes (within-gene range 0–3): AMZ2, AC005332.1, ARSG, SLC16A6, AC007780.1, WIPI1, MIR635, PRKAR1A, FAM20A, AC079210.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,089 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:100,208,254–100,591,324, 10 genes, copy number 5: LINC01104, LONRF2, CYCSP7, AC012493.1, CHST10, RALBP1P2, NMS, ARPP19P2, PDCL3, HMGN2P22.
- chr7:38,256,337–38,318,861, 10 genes, copy number 10 (within-gene range 4–10): TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9.
- chr7:142,636,924–142,802,748, 35 genes, copy number 7: TRBV21-1, TRBV22-1, TRBV23-1, TRBV24-1, MTRNR2L6, TRBV25-1, TRBVA, TRBV26, TRBVB, TRBV27, TRBV28, PGBD4P1, AC244472.1, TRBV29-1, PRSS1, PRSS2, PRSS3P1, WBP1LP1, TRBD1, TRBJ1-1, TRBJ1-2, TRBJ1-3, TRBJ1-4, TRBJ1-5, TRBJ1-6, TRBC1, TRBJ2-1, TRBJ2-2, TRBJ2-2P, TRBJ2-3, TRBJ2-4, TRBJ2-5, TRBJ2-6, TRBJ2-7, TRBC2.
- chr17:142,789–22,706,703, 927 genes, copy number 5 (broad region; genes not listed).
- chr19:37,907,208–38,208,369, 1 gene, copy number 5 (within-gene range 2–5): SIPA1L3.
- chr19:38,108,500–39,846,379, 106 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 870. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
